Somatic mutation profile of tumor specimen 1772e913-f62e-446a-8cf3-720348 (aliquot 1772e913-f62e-446a-8cf3-720348_D6) from CPTAC case 02OV005, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 1772e913-f62e-446a-8cf3-720348: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b8f758d-f88f-45ec-a8f1-673823f0d5ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 302a6175-8bba-4efd-a492-76e0f0 (Blood Derived Normal), aliquot 302a6175-8bba-4efd-a492-76e0f0_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f43f42e7-905e-4240-a0f6-4e21894fa863

The open-access MAF lists 97 somatic variants for this specimen: 64 protein-altering or splice-affecting, 18 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 18, Intron 8, RNA 3, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 2, 5'UTR 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNK17 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141016843, CM147368; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 174/252 reads (69%) | catalogued as rs1555525970, COSV52662121, COSV52858115, COSV53050787, COSV53082360; ClinVar: pathogenic; called by mutect2, varscan2
- TTN | c.71981dup p.N23994Kfs*5 (on ENST00000591111; = p.N16570Kfs*5 on NM_003319.4) | Frame Shift Ins (INS) | VAF 28/127 reads (22%) | catalogued as rs1553601017; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS4 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs765630081; called by muse, mutect2, varscan2
- AHNAK2 | c.6130G>A p.D2044N | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.981); catalogued as rs376858111; called by muse, mutect2, varscan2
- ARFGEF2 | c.1142T>G p.L381R | Missense Mutation (SNP) | VAF 23/526 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64216517; called by muse, mutect2
- CCDC116 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141137219; called by muse, mutect2, varscan2
- CCDC142 | c.1808C>T p.A603V (on ENST00000393965 / NM_001365575.2; = p.A596V on NM_032779.4) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs762591916; called by mutect2, varscan2
- CCDC27 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 32/140 reads (23%) | catalogued as rs760910706, COSV53898240; called by muse, mutect2, varscan2
- CCL27 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs372580675; called by muse, mutect2, varscan2
- DNAH14 | c.4594G>C p.D1532H (on ENST00000445597; = p.D1937H on NM_001367479.1) | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV60736732; called by muse, mutect2, varscan2
- ESRRB | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370122804; called by muse, mutect2, varscan2
- GPR88 | c.287C>G p.T96S | Missense Mutation (SNP) | VAF 86/416 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as COSV100159397; called by muse, mutect2, varscan2
- H2BC13 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100704403; called by muse, mutect2, varscan2
- IPO11 | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746394000, COSV100321769; called by muse, mutect2, varscan2
- LRP1 | c.6517C>T p.R2173W | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781626726; called by muse, mutect2, varscan2
- MAP3K19 | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV59642833; called by mutect2, varscan2
- MYB | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs963252355, COSV57199285; called by muse, mutect2, varscan2
- NBPF10 | c.1079C>G p.A360G | Missense Mutation (SNP) | VAF 34/413 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs781839260; called by muse, mutect2
- OR10H4 | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 99/450 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV100437765; called by muse, mutect2, varscan2
- PPP2R5C | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs114821166, COSV58271219; called by muse, mutect2, varscan2
- QRICH2 | c.4660C>T p.R1554W | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367825841; called by muse, mutect2, varscan2
- SEC13 | c.584+1G>A p.X195_splice (on ENST00000350697 / NM_183352.3; = p.X198_splice on NM_030673.4) | Splice Site (SNP) | VAF 25/140 reads (18%) | catalogued as rs1185001012; called by muse, mutect2
- SERPINB2 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100208239; called by muse, mutect2, varscan2
- SLC35B3 | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.107); catalogued as COSV59469586; called by muse, mutect2, varscan2
- SLC8A3 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149478505, COSV63523008, COSV63523018; called by muse, mutect2
- STARD9 | c.7489G>T p.D2497Y | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as rs1277220692; called by muse, mutect2, varscan2
- TAF1L | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244920150; called by muse, mutect2, varscan2
- TG | c.8203G>A p.G2735R | Missense Mutation (SNP) | VAF 87/686 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as rs777891366, COSV55070721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPM2 | c.3972C>T p.P1324= | Splice Region (SNP) | VAF 11/37 reads (30%) | catalogued as rs1330106324; called by muse, mutect2, varscan2
- TTN | c.49223A>G p.N16408S (on ENST00000591111; = p.N8984S on NM_003319.4) | Missense Mutation (SNP) | VAF 28/101 reads (28%) | PolyPhen probably damaging (0.994); catalogued as rs562393563; called by muse, mutect2, varscan2
- ZFHX4 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50514155; called by muse, mutect2, varscan2
- ZNF624 | c.378C>G p.D126E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1411968119; called by muse, mutect2, varscan2
- ADAM21 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by mutect2, varscan2
- ADGRL4 | c.1379C>A p.T460K | Missense Mutation (SNP) | VAF 17/321 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AL662899.2 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CA13 | c.479A>T p.K160M | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CDCA3 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CIT | c.3515G>T p.R1172L | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CLPSL2 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CNBD1 | c.525C>A p.N175K | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH1 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FIGNL1 | c.1198_1217del p.W400Rfs*4 | Frame Shift Del (DEL) | VAF 33/227 reads (15%) | called by mutect2, pindel, varscan2
- GNB1 | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GPR174 | c.32A>T p.D11V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HCN1 | c.1036T>A p.S346T | Missense Mutation (SNP) | VAF 112/536 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- KLRC4 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MACO1 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC17 | c.1892T>A p.I631K | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POGLUT2 | c.846-8_846dup p.R282_V283insSSR | In Frame Ins (INS) | VAF 9/48 reads (19%) | called by mutect2, varscan2
- PPP1R13B | c.2015_2016dup p.T673Pfs*34 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.544T>A p.C182S | Missense Mutation (SNP) | VAF 39/827 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- PRPS2 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 253/312 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SP140 | c.237+1G>A p.X79_splice | Splice Site (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- STRN4 | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SYMPK | c.3100G>T p.V1034L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TBC1D25 | c.234-2A>G p.X78_splice | Splice Site (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- TDRD12 | c.1711C>G p.L571V | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNFRSF21 | c.1094T>C p.I365T | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNRC6B | c.5057C>T p.A1686V (on ENST00000454349 / NM_001162501.2; = p.A1576V on NM_015088.3) | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- UBE2Q1 | c.418_421del p.K140Gfs*9 | Frame Shift Del (DEL) | VAF 57/96 reads (59%) | called by pindel, varscan2
- VIRMA | c.4225A>T p.T1409S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- XBP1 | c.607T>A p.S203T | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ZNF250 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- A2ML1 | c.2871G>A p.L957= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs777118635; called by muse, mutect2
- ANKDD1B | c.666C>T p.T222= | Silent (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- COX18 | c.72G>A p.P24= | Silent (SNP) | VAF 47/205 reads (23%) | called by muse, mutect2, varscan2
- CYP2F1 | c.189C>T p.G63= | Silent (SNP) | VAF 16/315 reads (5%) | called by muse, mutect2
- DNAH7 | c.1320G>A p.V440= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- HAPLN4 | c.249G>A p.R83= | Silent (SNP) | VAF 62/358 reads (17%) | called by muse, mutect2, varscan2
- LIFR | c.1413G>A p.K471= | Silent (SNP) | VAF 56/232 reads (24%) | catalogued as COSV54695569; called by muse, mutect2, varscan2
- MTCL1 | c.3156G>T p.R1052= (on ENST00000306329 / NM_001378206.1; = p.R733= on NM_015210.4) | Silent (SNP) | VAF 54/284 reads (19%) | catalogued as rs755765155; called by mutect2, varscan2
- NPAT | c.3705T>C p.T1235= | Silent (SNP) | VAF 60/236 reads (25%) | called by muse, mutect2, varscan2
- PIF1 | c.999C>T p.F333= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs137960587; called by muse, mutect2, varscan2
- PPP2R2B | c.804G>A p.P268= (on ENST00000394409; = p.P334= on NM_181674.2) | Silent (SNP) | VAF 37/187 reads (20%) | catalogued as rs147383897; called by muse, mutect2, varscan2
- ROCK1 | c.3016T>C p.L1006= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs1462389978; called by muse, mutect2, varscan2
- RSU1 | c.540C>A p.T180= | Silent (SNP) | VAF 14/82 reads (17%) | called by mutect2, varscan2
- SLC25A31 | c.60C>T p.F20= | Silent (SNP) | VAF 77/258 reads (30%) | called by muse, mutect2, varscan2
- TACC2 | c.3771C>T p.S1257= | Silent (SNP) | VAF 70/205 reads (34%) | catalogued as COSV100553842; called by muse, mutect2, varscan2
- UBA2 | c.1299A>G p.A433= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV55827628; called by muse, mutect2, varscan2
- XIRP1 | c.2166G>A p.A722= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs150133594; called by muse, mutect2, varscan2
- ZDHHC18 | c.741G>T p.L247= | Silent (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- AC106795.1 | n.780dup | RNA (INS) | VAF 48/212 reads (23%) | called by mutect2, varscan2
- DIP2C | c.157+1594G>T | Intron (SNP) | VAF 53/282 reads (19%) | catalogued as COSV99793245; called by muse, mutect2, varscan2
- FAM21FP | n.328A>C | RNA (SNP) | VAF 32/175 reads (18%) | called by muse, mutect2, varscan2
- FAP | c.1402+1164C>T | Intron (SNP) | VAF 45/208 reads (22%) | called by muse, mutect2, varscan2
- GPER1 | c.*190C>A | 3'UTR (SNP) | VAF 42/286 reads (15%) | called by mutect2, varscan2
- IGKV1D-27 | n.291C>A | RNA (SNP) | VAF 74/279 reads (27%) | called by mutect2, varscan2
- KIF2C | c.1752-68C>T | Intron (SNP) | VAF 37/157 reads (24%) | catalogued as rs957434114; called by muse, mutect2, varscan2
- LRRC8D | c.-117G>C | 5'UTR (SNP) | VAF 24/141 reads (17%) | catalogued as rs1314019336; called by muse, mutect2, varscan2
- SART1 | c.372-35T>G | Intron (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- SCN9A | c.688+129T>A | Intron (SNP) | VAF 16/315 reads (5%) | called by muse, mutect2
- SMTN | c.51+1862C>G | Intron (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- SNORD52 | chr6:31837339 G>A | 3'Flank (SNP) | VAF 27/239 reads (11%) | catalogued as rs141078904; called by muse, mutect2, varscan2
- STX3 | c.*91A>T | 3'UTR (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2
- SYNE1 | c.4461+34G>C | Intron (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- TSKS | c.663+238T>G | Intron (SNP) | VAF 16/46 reads (35%) | catalogued as rs775706279; called by muse, mutect2, varscan2
